Somatic mutation profile of tumor specimen TCGA-94-7557-01A (aliquot TCGA-94-7557-01A-11D-2122-08) from TCGA case TCGA-94-7557, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.4 years (26,802 days).
Specimen TCGA-94-7557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dab9191-9b91-434b-86e5-872be5d1b0b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-7557-10A (Blood Derived Normal), aliquot TCGA-94-7557-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9d3bde7-f380-46c9-9048-f9e9bed11fff

The open-access MAF lists 102 somatic variants for this specimen: 66 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 34, Nonsense Mutation 5, Frame Shift Del 3, Intron 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1880A>C p.K627T (on ENST00000404938 / NM_001163941.2; = p.K182T on NM_178559.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99330038; called by muse, mutect2, varscan2
- ADAMTS12 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs1480546938, COSV100711765; called by muse, mutect2, varscan2
- ALS2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99970175; called by muse, mutect2, varscan2
- AMIGO1 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV100881118; called by muse, mutect2, varscan2
- ANKRD11 | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99970888; called by muse, mutect2, varscan2
- ANOS1 | c.727-1G>A p.X243_splice | Splice Site (SNP) | VAF 24/41 reads (59%) | catalogued as CS983700, COSV99391597; called by muse, mutect2, varscan2
- APLP2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99600155; called by muse, mutect2, varscan2
- ARID5B | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99690615; called by muse, mutect2, varscan2
- ASTE1 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757364413, COSV99394048; called by muse, mutect2, varscan2
- C14orf39 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100408179; called by muse, mutect2, varscan2
- CAVIN4 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as COSV56866487, COSV56867445; called by muse, mutect2, varscan2
- CCL3L3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 111/792 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1473476410; called by muse, varscan2
- CD109 | c.2902C>A p.Q968K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV99754859; called by muse, mutect2, varscan2
- CD163L1 | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV100550798, COSV58013325; called by muse, mutect2, varscan2
- CFHR5 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV99888510, COSV99889916; called by muse, mutect2
- COQ3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV99633096; called by muse, mutect2, varscan2
- CSPP1 | c.2534C>T p.A845V (on ENST00000676605; = p.A804V on NM_024790.6) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99140155; called by muse, mutect2, varscan2
- CTNNA2 | c.22A>T p.I8F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100786494, COSV63557911; called by muse, mutect2, varscan2
- DARS1 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99928016; called by muse, mutect2, varscan2
- DEDD2 | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100260398; called by muse, mutect2
- DNAJC22 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as rs757250285, COSV101222622; called by muse, mutect2, varscan2
- FAM193B | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100286882; called by muse, mutect2, varscan2
- FBLN1 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV99411720; called by muse, mutect2
- GAS2L3 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs777692991, COSV99903227; called by muse, mutect2, varscan2
- GGN | c.1711C>G p.Q571E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.166); catalogued as COSV53058483; called by muse, mutect2, varscan2
- HTR3A | c.872T>A p.V291D | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100248681; called by muse, mutect2, varscan2
- IFIT2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs1389691613, COSV51078771; called by muse, mutect2
- IPMK | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100470665; called by muse, mutect2, varscan2
- KIF20B | c.2683G>C p.E895Q (on ENST00000371728 / NM_001284259.2; = p.E855Q on NM_016195.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV53307063, COSV99590875; called by muse, mutect2, varscan2
- KIR2DL3 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100667855; called by muse, mutect2
- KLK3 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs746367915, COSV100386144; called by muse, mutect2, varscan2
- LMAN2L | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359566006, COSV99383695; called by muse, mutect2, varscan2
- MYSM1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as COSV101284078; called by muse, mutect2, varscan2
- NAA11 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV99727659; called by muse, mutect2
- NCL | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.173); catalogued as rs758211775, COSV100502501; called by muse, mutect2, varscan2
- NEXMIF | c.2573C>T p.T858I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99279577; called by muse, mutect2, varscan2
- OR5H1 | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1298155677, COSV100641796, COSV63401657; called by muse, mutect2, varscan2
- PBX3 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV100655574; called by muse, mutect2, varscan2
- PCDH1 | c.2569G>T p.V857L | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV99747142; called by muse, mutect2, varscan2
- PDE4A | c.1390C>T p.L464F (on ENST00000380702 / NM_001111307.2; = p.L225F on NM_006202.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99535420; called by muse, mutect2, varscan2
- PDE4A | c.1910C>T p.S637F (on ENST00000380702 / NM_001111307.2; = p.S398F on NM_006202.3) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV53351407; called by muse, mutect2, varscan2
- PDE4A | c.2264C>T p.S755F (on ENST00000380702 / NM_001111307.2; = p.S516F on NM_006202.3) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV53364244; called by muse, mutect2, varscan2
- PJA1 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100824842; called by muse, mutect2, varscan2
- PRDM9 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV57011290, COSV99691471; called by muse, mutect2, varscan2
- RHO | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV56214161; called by muse, mutect2, varscan2
- RYR1 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157293156, COSV100617249; called by muse, mutect2, varscan2
- S1PR5 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs202083643, COSV100330821; called by muse, mutect2, varscan2
- SH3BP5L | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as rs774976778, COSV100822129; called by muse, mutect2, varscan2
- SIK2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs746560391, COSV100232440; called by muse, mutect2, varscan2
- SLC17A8 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100035928, COSV60126532; called by muse, mutect2
- STXBP2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); catalogued as COSV99657474; called by muse, mutect2, varscan2
- STYXL2 | c.1542G>C p.R514S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99610025; called by muse, mutect2, varscan2
- SZT2 | c.4328G>T p.S1443I (on ENST00000634258 / NM_001365999.1; = p.S1386I on NM_015284.4) | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs765781424, COSV100987714; called by muse, mutect2, varscan2
- TARDBP | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99534510; called by muse, mutect2, varscan2
- TMEM132B | c.1822G>T p.V608L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as rs1326867100, COSV100171231; called by muse, mutect2, varscan2
- TMEM63B | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV99442235; called by muse, mutect2, varscan2
- TMPRSS9 | c.2419A>G p.T807A (on ENST00000648592; = p.T773A on NM_182973.2) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs774582605, COSV99296142; called by muse, mutect2, varscan2
- TSPYL5 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV100439176; called by muse, mutect2, varscan2
- UBXN4 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV99739718; called by muse, mutect2, varscan2
- ZNF81 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100096309; called by muse, mutect2, varscan2
- ZPR1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746836723, COSV99911532; called by muse, mutect2, varscan2
- DAGLA | c.2360_2384del p.E787Afs*40 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- NAA15 | c.1615_1624del p.V539* | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- OPN1MW | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PRAG1 | c.2704dup p.R902Kfs*70 | Frame Shift Ins (INS) | VAF 18/110 reads (16%) | called by mutect2, pindel
- TP53 | c.190_191delinsT p.P64Sfs*59 | Frame Shift Del (DEL) | VAF 78/230 reads (34%) | called by pindel, varscan2*
- ARFGEF2 | c.4971C>T p.S1657= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1179552636, COSV100904538; called by muse, mutect2, varscan2
- ASTN1 | c.2589C>G p.G863= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV56064988, COSV99923381; called by muse, mutect2
- CDK10 | c.324C>T p.N108= (on ENST00000353379 / NM_052988.5; = p.N37= on NM_052987.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1055365150, COSV99232604; called by muse, mutect2, varscan2
- CELF2 | c.345C>T p.P115= (on ENST00000416382 / NM_001025077.3; = p.P122= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100257936, COSV100258622; called by muse, mutect2
- CYC1 | c.780A>G p.P260= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100010638; called by mutect2, varscan2
- DPH2 | c.1287T>C p.H429= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV99356696; called by muse, mutect2, varscan2
- FAM110B | c.361C>T p.L121= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs757100650, COSV100826299; called by muse, mutect2, varscan2
- GPD1 | c.72C>A p.G24= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV99993913; called by muse, mutect2
- HIPK1 | c.2190C>T p.S730= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs367569194, COSV100479763; called by muse, mutect2, varscan2
- ISCA2 | c.348G>T p.V116= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99467096; called by mutect2, varscan2
- KEAP1 | c.915C>T p.F305= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs778502600, COSV50267571, COSV99408381; called by muse, mutect2, varscan2
- KEAP1 | c.555C>T p.I185= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1376350378, COSV99408386; called by muse, mutect2, varscan2
- KEAP1 | c.459C>T p.L153= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1489089735, COSV99408389; called by muse, mutect2, varscan2
- KRTAP4-5 | c.6C>T p.V2= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV100576857; called by muse, mutect2, varscan2
- LAMA1 | c.1827C>T p.D609= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1366414167, COSV67535858; called by muse, mutect2, varscan2
- LAMA2 | c.5469C>T p.S1823= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs753886576, COSV70338041; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LILRB5 | c.873C>T p.G291= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV60258816; called by muse, mutect2, varscan2
- LRIG1 | c.1014C>T p.L338= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1325416509, COSV99834581; called by muse, mutect2, varscan2
- MGAM | c.4890C>T p.G1630= | Silent (SNP) | VAF 25/262 reads (10%) | catalogued as rs1393697705, COSV72074514, COSV72076098; called by muse, mutect2
- NUP98 | c.4282C>T p.L1428= (on ENST00000359171 / NM_001365126.1; = p.L1411= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV100263664; called by muse, mutect2, varscan2
- PDE4A | c.631C>T p.L211= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV99535414; called by muse, mutect2, varscan2
- PDE4A | c.1563C>A p.I521= (on ENST00000380702 / NM_001111307.2; = p.I282= on NM_006202.3) | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99533952; called by muse, mutect2, varscan2
- PHOSPHO1 | c.375C>T p.N125= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs770848037, COSV99865889; called by muse, varscan2
- PPIL1 | c.447C>T p.S149= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV101033968; called by muse, mutect2, varscan2
- PRAMEF8 | c.945C>T p.C315= | Silent (SNP) | VAF 13/355 reads (4%) | called by muse, mutect2
- SERPINA3 | c.246C>T p.T82= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs756445395, COSV67585581; called by muse, mutect2, varscan2
- SYNE2 | c.6054G>A p.L2018= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100648596, COSV59943823; called by muse, varscan2
- SYT10 | c.27G>A p.V9= | Silent (SNP) | VAF 18/233 reads (8%) | catalogued as COSV99952091; called by muse, mutect2
- TAF6 | c.1377C>G p.L459= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV100612893; called by muse, mutect2, varscan2
- TENT5A | c.438C>T p.A146= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs761264358, COSV100199205; called by muse, mutect2
- TLR7 | c.681A>G p.L227= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV101028192; called by muse, mutect2, varscan2
- TUBA3D | c.888C>T p.F296= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs532066293, COSV58310581; called by muse, mutect2, varscan2
- USH2A | c.3192T>C p.V1064= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV100243806; called by muse, mutect2, varscan2
- ZNHIT2 | c.147G>A p.Q49= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99658210; called by muse, mutect2
- OSTCP1 | n.582G>A | RNA (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10360+2572A>G | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100634312; called by muse, mutect2, varscan2
